CCDI case PBCNTJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/d0a4ceb3-7de4-4488-a9ca-22c5fe2041b9

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Prostate gland; Age at diagnosis: 12.2 years (4,450 days).

Biospecimens (3 samples)
- Sample 0DWHZ6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWI1G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWI1W: Tissue type: Tumor; Specimen type: Solid Tissue.
